Somatic mutation profile of tumor specimen TCGA-CK-4947-01B (aliquot TCGA-CK-4947-01B-11D-1650-10) from TCGA case TCGA-CK-4947, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 46.5 years (16,980 days).
Specimen TCGA-CK-4947-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25e70d0b-21b0-473d-adf9-dbf2ecc72e78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-4947-10A (Blood Derived Normal), aliquot TCGA-CK-4947-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91276322-8ae9-488a-889a-885941949a5c

The open-access MAF lists 105 somatic variants for this specimen: 80 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 23, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 2, Translation Start Site 1, RNA 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 58/232 reads (25%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 91/286 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC12 | c.3284C>T p.S1095L | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200832541, COSV60913543; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2577C>A p.H859Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101001176; called by muse, mutect2
- ATM | c.9089G>T p.G3030V | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876658529, COSV53736717, COSV53762839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2C1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 42/130 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.599); catalogued as COSV60763856; called by muse, mutect2
- C10orf90 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs754901315, COSV99502937; called by muse, varscan2
- CADPS | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs916748914, COSV51875550; called by muse, mutect2, varscan2
- CCDC150 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as COSV55875503, COSV55879744; called by muse, mutect2, varscan2
- CCNT1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 97/306 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs575488596, COSV56066300; called by muse, mutect2, varscan2
- CDH8 | c.1943A>T p.K648I | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV100181986, COSV54907409; called by muse, mutect2, varscan2
- CHST9 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 116/216 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV52452109; called by muse, mutect2, varscan2
- DDR1 | c.640A>C p.T214P | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV100240913; called by muse, mutect2, varscan2
- DNAJB6 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1394317103, COSV51101426; called by muse, mutect2, varscan2
- DPP6 | c.2581G>A p.D861N (on ENST00000377770 / NM_001364500.2; = p.D799N on NM_001936.5) | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV59651383; called by muse, mutect2, varscan2
- DPP9 | c.275C>A p.P92H (on ENST00000598800; = p.P121H on NM_139159.5) | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53595150; called by muse, mutect2, varscan2
- FAS | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 164/517 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.264); catalogued as COSV58240401; called by muse, mutect2, varscan2
- FAT3 | c.5197C>T p.R1733C | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs374615122; called by muse, varscan2
- G6PD | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100854924; called by muse, mutect2, varscan2
- GEN1 | c.1561T>C p.S521P | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100437731; called by muse, mutect2, varscan2
- GJD2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs202150693, COSV51747514; called by muse, mutect2, varscan2
- GLT8D2 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as rs150432657, COSV62563529; called by muse, mutect2
- GPR132 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.013); catalogued as COSV61678495; called by muse, mutect2, varscan2
- GPR88 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV59291256; called by muse, mutect2, varscan2
- GRIA2 | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348382463, COSV52384836; called by muse, mutect2, varscan2
- GRM5 | c.2679C>A p.F893L | Missense Mutation (SNP) | VAF 114/399 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.878); catalogued as COSV59634927; called by muse, mutect2, varscan2
- HDX | c.1976T>A p.L659* | Nonsense Mutation (SNP) | VAF 109/321 reads (34%) | catalogued as COSV52984211; called by muse, mutect2, varscan2
- IL34 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.648); catalogued as rs369011177; called by muse, mutect2, varscan2
- ILDR2 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359594941, COSV54831021; called by muse, mutect2, varscan2
- IRAK1 | c.1141A>T p.T381S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV64114190; called by muse, mutect2, varscan2
- JPH3 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771941317, COSV52466654; called by muse, mutect2, varscan2
- KANSL2 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760561861, COSV63480643; called by muse, mutect2, varscan2
- KCNA5 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs747919632, COSV52904716, COSV52909071; called by muse, mutect2, varscan2
- KLRK1 | c.590A>C p.K197T | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.957); catalogued as COSV53700161; called by muse, mutect2, varscan2
- LANCL2 | c.731A>C p.K244T | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.115); catalogued as COSV54653472; called by muse, mutect2, varscan2
- MAP1LC3A | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV54164717; called by muse, mutect2, varscan2
- MFSD4B | c.35C>T p.T12M (on ENST00000368847; = p.N107= on NM_153369.4) | Missense Mutation (SNP) | VAF 99/282 reads (35%) | catalogued as rs769996329, COSV64349633; called by muse, mutect2, varscan2
- MMP26 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV56174412; called by muse, mutect2, varscan2
- MON1B | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs1184718449, COSV50255673; called by muse, mutect2, varscan2
- MOV10 | c.1663C>G p.P555A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100659815, COSV62492921; called by muse, mutect2, varscan2
- MUC16 | c.41183G>T p.S13728I | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV66697641; called by muse, mutect2, varscan2
- MXRA5 | c.6460C>T p.R2154W | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54226273; called by muse, mutect2, varscan2
- MYH3 | c.5165C>A p.T1722N | Missense Mutation (SNP) | VAF 108/383 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV56871108; called by muse, mutect2, varscan2
- NOX4 | c.1218-2A>G p.X406_splice | Splice Site (SNP) | VAF 106/339 reads (31%) | catalogued as COSV99629405, COSV99630681; called by muse, mutect2, varscan2
- NRXN1 | c.1388T>C p.M463T | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.586); catalogued as COSV58502176; called by muse, mutect2
- NUAK2 | c.467T>C p.F156S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV100903952, COSV100904190; called by muse, mutect2, varscan2
- OR10AG1 | c.721T>A p.L241I | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV56635392; called by muse, mutect2
- OR2M4 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1192709932, COSV60708803, COSV60709747; called by muse, mutect2, varscan2
- PARP15 | c.1991T>G p.F664C (on ENST00000464300 / NM_001113523.3; = p.F430C on NM_152615.2) | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs747513128, COSV59975501; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDH19 | c.2719A>T p.S907C (on ENST00000373034 / NM_001184880.2; = p.S859C on NM_020766.3) | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99718919; called by muse, mutect2, varscan2
- PLEKHG4B | c.3224G>A p.R1075Q (on ENST00000283426; = p.R1431Q on NM_052909.5) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs185255672, COSV52057041, COSV99360736; called by muse, mutect2
- PLPPR1 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100882956; called by muse, mutect2, varscan2
- RNF213 | c.11125G>A p.V3709I | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as rs775973536, COSV60390315; called by muse, mutect2, varscan2
- ROBO1 | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs1319728616, COSV71393750; called by muse, mutect2, varscan2
- ROR1 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.568); catalogued as COSV64294423; called by muse, mutect2, varscan2
- RTN4R | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99244817; called by muse, mutect2
- SAGE1 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as COSV100186564; called by muse, mutect2, varscan2
- SALL3 | c.2858G>A p.R953H | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.08); PolyPhen benign (0.2); catalogued as rs755054197, COSV73306733; called by muse, mutect2, varscan2
- SCN11A | c.4508T>C p.L1503P | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56580162; called by muse, mutect2, varscan2
- SEC14L5 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.74); catalogued as rs748043090, COSV52041419; called by muse, mutect2, varscan2
- SLC25A35 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.876); catalogued as COSV56840442; called by muse, mutect2, varscan2
- SLC43A3 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752588393, COSV61449747; called by muse, mutect2, varscan2
- SOX9 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV55424579; called by muse, mutect2, varscan2
- STK40 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs773276972, COSV63737343; called by muse, mutect2, varscan2
- TLR9 | c.2732G>A p.R911H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62348981; called by muse, mutect2, varscan2
- TOLLIP | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.269); catalogued as rs936636982, COSV55138688; called by muse, mutect2, varscan2
- TTC7B | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as rs148995908; called by muse, mutect2, varscan2
- TTLL9 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368805639; called by muse, mutect2, varscan2
- WDFY3 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.121); catalogued as COSV55694258; called by muse, mutect2, varscan2
- WDR17 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 106/461 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54586404; called by muse, mutect2, varscan2
- WDR3 | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.498); catalogued as rs200959855, COSV100832061, COSV62525787; called by muse, mutect2, varscan2
- WWC3 | c.2819G>A p.R940Q | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251163153, CM137518, COSV66508859; called by muse, mutect2, varscan2
- ZNF345 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59325649; called by muse, mutect2, varscan2
- ZNF576 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV60671737; called by muse, mutect2, varscan2
- ACOT12 | c.507del p.F169Lfs*59 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | called by mutect2, pindel, varscan2
- ANXA8 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 80/503 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.035); called by muse, varscan2
- SOX9 | c.1348_1351dup p.Y451Ffs*128 | Frame Shift Ins (INS) | VAF 20/73 reads (27%) | called by mutect2, pindel, varscan2
- TCF7L2 | c.1445dup p.C486Vfs*8 (on ENST00000355995 / NM_001367943.1; = p.C463Vfs*8 on NM_030756.5) | Frame Shift Ins (INS) | VAF 50/153 reads (33%) | called by mutect2, pindel, varscan2
- TTN | c.79878del p.K26626Nfs*34 (on ENST00000591111; = p.K19202Nfs*34 on NM_003319.4) | Frame Shift Del (DEL) | VAF 79/267 reads (30%) | called by mutect2, pindel, varscan2
- ATAD2 | c.2220T>C p.S740= | Silent (SNP) | VAF 24/500 reads (5%) | catalogued as COSV99783977; called by muse, mutect2
- C12orf50 | c.987G>A p.A329= | Silent (SNP) | VAF 134/509 reads (26%) | catalogued as rs762685869, COSV100072284, COSV53894688; called by muse, mutect2, varscan2
- CARMIL2 | c.3399C>T p.G1133= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs375307002, COSV54666296; called by muse, mutect2, varscan2
- CEP85L | c.933T>G p.G311= | Silent (SNP) | VAF 72/250 reads (29%) | catalogued as COSV100682494; called by muse, varscan2
- CRB1 | c.1686C>A p.T562= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV66334788; called by muse, mutect2, varscan2
- DHRS12 | c.696C>T p.A232= (on ENST00000444610 / NM_001377930.1; = p.A183= on NM_024705.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/193 reads (18%) | catalogued as rs764350346, COSV54473902; called by muse, mutect2, varscan2
- FBP2 | c.51C>T p.Y17= | Silent (SNP) | VAF 60/258 reads (23%) | catalogued as rs774531216, COSV64696058; called by muse, mutect2, varscan2
- FDFT1 | c.534G>A p.L178= | Silent (SNP) | VAF 72/235 reads (31%) | catalogued as rs542897126, COSV55044316; called by muse, mutect2, varscan2
- FIGN | c.1857G>A p.S619= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs186183930; called by muse, mutect2, varscan2
- GPR26 | c.522C>T p.G174= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as rs1194731501, COSV99500719; called by muse, mutect2
- GPR37 | c.789G>A p.A263= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV58256104; called by muse, mutect2
- GRN | c.828G>A p.A276= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs761530797, COSV50006406; called by muse, mutect2, varscan2
- H3-4 | c.105C>T p.G35= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV64210559; called by muse, mutect2, varscan2
- HNF4G | c.249A>G p.Q83= (on ENST00000354370 / NM_001330561.2; = p.Q130= on NM_004133.5) | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV62974878; called by muse, mutect2
- HOXA3 | c.129C>T p.G43= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV57828186; called by muse, mutect2, varscan2
- HSF5 | c.849A>G p.Q283= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV60420275; called by muse, mutect2, varscan2
- JCAD | c.1050G>A p.P350= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs780771035, COSV64758807; called by muse, mutect2, varscan2
- NCLN | c.1611C>T p.G537= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99859651; called by muse, mutect2, varscan2
- NDUFB10 | c.438C>A p.A146= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99238671; called by muse, mutect2, varscan2
- PRKACG | c.606C>G p.T202= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99597810; called by muse, mutect2
- PRRC2C | c.6147C>T p.L2049= (on ENST00000367742; = p.L2047= on NM_015172.4) | Silent (SNP) | VAF 83/313 reads (27%) | catalogued as rs527862519, COSV100145598, COSV58906309; called by muse, mutect2, varscan2
- PXDNL | c.2193C>T p.D731= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs553366367, COSV62484401, COSV62493539; called by muse, mutect2, varscan2
- RIMS1 | c.3591A>T p.A1197= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV53490894; called by muse, mutect2, varscan2
- PDGFD | c.125-36759G>A | Intron (SNP) | VAF 21/68 reads (31%) | catalogued as rs111318551, COSV56373913; called by muse, mutect2, varscan2
- SSPOP | n.8514C>T | RNA (SNP) | VAF 27/91 reads (30%) | catalogued as rs746136638, COSV100946956; called by muse, mutect2, varscan2
